Somatic mutation profile of tumor specimen ALCH-ADGG-TTP1-A (aliquot ALCH-ADGG-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADGG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,045 days).
Specimen ALCH-ADGG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95da9204-3997-40e5-a763-d735781d82e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADGG-NB1-A (Blood Derived Normal), aliquot ALCH-ADGG-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91a00b21-2275-43e0-94e7-21379f7b2056

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, Splice Region 1, 5'UTR 1, Splice Site 1, Intron 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 74/438 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 102/449 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 59/375 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770355300; called by muse, mutect2
- CACNA1G | c.3920G>A p.R1307H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61720272; called by muse, mutect2, varscan2
- CNKSR2 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | catalogued as COSV54260971; called by muse, mutect2
- COL5A3 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758573683; called by muse, mutect2, varscan2
- CYP4F3 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs483352698, COSV55412898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF3I | c.183C>T p.D61= | Splice Region (SNP) | VAF 44/167 reads (26%) | catalogued as rs780091515, COSV100557316; called by muse, mutect2, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GRID2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs781013535, COSV99945894; called by muse, mutect2, varscan2
- KCNMA1 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1236775792, COSV54246667; called by muse, mutect2, varscan2
- LRFN5 | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV53268220; called by muse, mutect2
- LRRC7 | c.2788G>A p.V930I (on ENST00000651989 / NM_001370785.2; = p.V897I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.011); catalogued as rs758138383, COSV50503978; called by muse, mutect2, varscan2
- MED12 | c.5815C>T p.Q1939* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs867091628, COSV61359628; called by muse, mutect2, varscan2
- MYH2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs751560989, COSV55440308; called by muse, mutect2, varscan2
- PDZD7 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs768381051, COSV64645534; called by muse, mutect2, varscan2
- TBC1D19 | c.275T>A p.V92E | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99336057; called by muse, mutect2, varscan2
- TSR3 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs148457434; called by muse, mutect2, varscan2
- BMPR2 | c.2397del p.H800Mfs*3 | Frame Shift Del (DEL) | VAF 47/275 reads (17%) | called by mutect2, pindel, varscan2
- CCR4 | c.842del p.Y281Sfs*86 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- CIC | c.66C>G p.F22L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CLTC | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL20A1 | c.3752G>A p.G1251E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CSMD3 | c.6635T>A p.F2212Y (on ENST00000297405 / NM_001363185.1; = p.F2108Y on NM_052900.3) | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.10629A>T p.Q3543H | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAK4 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KLRC3 | c.26del p.S9* | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel
- OTOA | c.1528A>C p.K510Q (on ENST00000286149; = p.K496Q on NM_144672.4) | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.3604A>C p.K1202Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHB9 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PHIP | c.3379+1G>C p.X1127_splice | Splice Site (SNP) | VAF 44/157 reads (28%) | called by muse, mutect2, varscan2
- PLA2G4C | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); called by muse, mutect2
- SLC13A5 | c.1595T>G p.M532R | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SPHK2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TASOR2 | c.3327C>A p.D1109E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USHBP1 | c.1820A>G p.Q607R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BBS9 | c.825A>G p.G275= | Silent (SNP) | VAF 73/343 reads (21%) | called by muse, mutect2, varscan2
- FOXB1 | c.192C>T p.N64= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs767875999; called by muse, mutect2, varscan2
- KANK4 | c.2265C>T p.C755= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs1015493511; called by muse, mutect2, varscan2
- LRP4 | c.4245C>T p.N1415= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs185084650; called by muse, mutect2, varscan2
- LRRC10B | c.405G>A p.L135= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV65223471, COSV65223626; called by muse, mutect2, varscan2
- MATK | c.1215G>A p.S405= (on ENST00000310132 / NM_139355.3; = p.S406= on NM_002378.4) | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs756824162; called by muse, mutect2, varscan2
- MUC2 | c.1032C>T p.T344= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as rs866843789; called by muse, mutect2, varscan2
- PCSK2 | c.1011C>T p.D337= | Silent (SNP) | VAF 15/245 reads (6%) | catalogued as rs1020319388; called by muse, mutect2
- PHRF1 | c.4767G>A p.K1589= (on ENST00000264555 / NM_001286581.2; = p.K1588= on NM_020901.4) | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs1328556305; called by muse, mutect2
- RETNLB | c.237C>A p.G79= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs200893841; called by muse, varscan2
- ZDHHC20 | c.535C>T p.L179= | Silent (SNP) | VAF 17/264 reads (6%) | called by muse, mutect2
- ZNF717 | c.432G>A p.L144= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- FAM183BP | n.593G>A | RNA (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- H3C1 | c.-4C>T | 5'UTR (SNP) | VAF 23/175 reads (13%) | catalogued as rs189961348; called by muse, mutect2, varscan2
- IGHD2-2 | chr14:105921223 C>T | 5'Flank (SNP) | VAF 31/116 reads (27%) | catalogued as rs782469359; called by muse, mutect2, varscan2
- LY6K | c.218-534C>T | Intron (SNP) | VAF 30/175 reads (17%) | catalogued as rs1453887570; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092294 T>A | 3'Flank (SNP) | VAF 64/241 reads (27%) | called by muse, mutect2, varscan2
- UBE2DNL | n.434C>T | RNA (SNP) | VAF 4/26 reads (15%) | catalogued as rs1199528686; called by muse, varscan2
